Somatic mutation profile of tumor specimen MMRF_1994_1_BM_CD138pos (aliquot MMRF_1994_1_BM_CD138pos_T1_KBS5U_L07275) from MMRF case MMRF_1994, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 89.8 years (32,805 days).
Specimen MMRF_1994_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c44b6d98-b6b1-4b27-9114-ddcc94a5d667.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1994_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1994_1_PB_Whole_C2_KBS5U_L07276; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6309e614-2809-4fb4-abc2-d2486498599e

The open-access MAF lists 231 somatic variants for this specimen: 100 protein-altering or splice-affecting, 27 silent, 104 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 88, 3'UTR 56, Silent 27, Intron 24, 5'UTR 10, 3'Flank 7, Splice Site 4, RNA 4, 5'Flank 3, Splice Region 2, Nonsense Mutation 2, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.37G>C p.G13R | Missense Mutation (SNP) | VAF 169/479 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs121434595, COSV54736386, COSV54736476, COSV54736550; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAP1 | c.415C>T p.R139C | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs760068363, COSV56216316; called by muse, mutect2, varscan2
- ALLC | c.95C>T p.P32L | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs540280415, COSV52998114; called by muse, mutect2, varscan2
- BAG3 | c.926G>A p.R309Q | Missense Mutation (SNP) | VAF 44/140 reads (31%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as rs774137001, COSV64842858; ClinVar: uncertain significance; called by muse, mutect2
- CHD1L | c.487C>G p.L163V | Missense Mutation (SNP) | VAF 42/195 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as COSV63614421; called by muse, mutect2, varscan2
- CHD5 | c.5245G>A p.V1749M | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs749269983; called by muse, mutect2, varscan2
- CLCA4 | c.466G>C p.E156Q | Missense Mutation (SNP) | VAF 62/158 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); catalogued as COSV55369196; called by muse, mutect2, varscan2
- CLMN | c.499T>G p.S167A | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.046); catalogued as rs1566870759; called by muse, mutect2, varscan2
- COL11A1 | c.97G>T p.V33F | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT tolerated (0.17); PolyPhen benign (0.159); catalogued as COSV100617824; called by muse, mutect2, varscan2
- DIS3 | c.2366G>A p.R789Q | Missense Mutation (SNP) | VAF 119/122 reads (98%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs141022568; called by muse, mutect2, varscan2
- DNAH2 | c.2978G>A p.R993H | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.235); catalogued as COSV66721914; called by muse, mutect2
- DUSP2 | c.390A>C p.G130= | Splice Region (SNP) | VAF 40/99 reads (40%) | catalogued as rs748272134; called by muse, mutect2, varscan2
- EML1 | c.1105T>C p.C369R | Missense Mutation (SNP) | VAF 78/213 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); catalogued as rs1321358203; called by muse, mutect2, varscan2
- FAT4 | c.10697G>A p.G3566E | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58678337; called by muse, mutect2, varscan2
- FITM2 | c.373C>T p.P125S | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV101201992; called by muse, mutect2, varscan2
- GSE1 | c.366dup p.V123Rfs*17 | Frame Shift Ins (INS) | VAF 7/8 reads (88%) | catalogued as rs754199513; called by mutect2, varscan2
- HRH1 | c.646G>T p.A216S | Missense Mutation (SNP) | VAF 12/135 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as rs766424758; called by muse, mutect2
- IGLV3-1 | c.197T>G p.I66S | Missense Mutation (SNP) | VAF 108/110 reads (98%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs559746623; called by muse, varscan2
- IGLV3-1 | c.302A>C p.E101A | Missense Mutation (SNP) | VAF 98/98 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs532827838; called by muse, varscan2
- IGLV3-1 | c.314A>C p.Y105S | Missense Mutation (SNP) | VAF 104/104 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as rs185803370; called by muse, varscan2
- LARP1 | c.1855C>T p.R619W (on ENST00000518297 / NM_033551.3; = p.R542W on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs958413075; called by muse, mutect2, varscan2
- MAPK4 | c.185C>T p.A62V | Missense Mutation (SNP) | VAF 74/155 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs745586840, COSV68542485, COSV68543504; called by muse, mutect2, varscan2
- MICAL2 | c.980C>T p.A327V | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs369887102; called by muse, mutect2, varscan2
- MMP17 | c.167T>C p.L56P | Missense Mutation (SNP) | VAF 27/47 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs972482426; called by muse, mutect2, varscan2
- NAT8L | c.598C>T p.R200W | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.971); catalogued as rs1309041395, COSV59051230; called by muse, mutect2, varscan2
- NPAT | c.3166G>A p.A1056T | Missense Mutation (SNP) | VAF 44/104 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.022); catalogued as rs767410422; called by muse, mutect2, varscan2
- OR10J1 | c.238A>G p.R80G | Missense Mutation (SNP) | VAF 80/412 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as rs1398140982, COSV101420085, COSV71129779; called by muse, mutect2, varscan2
- OR8J3 | c.126C>A p.N42K | Missense Mutation (SNP) | VAF 16/143 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56882503; called by muse, mutect2, varscan2
- PCDHB16 | c.1970C>T p.T657M | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs1174926521; called by muse, mutect2, varscan2
- PHLDB1 | c.3670C>T p.R1224C | Missense Mutation (SNP) | VAF 93/211 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as rs781987006, COSV61880685; called by muse, mutect2, varscan2
- RBP3 | c.1777G>A p.V593M | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs782377821; called by muse, mutect2, varscan2
- RHAG | c.310C>A p.Q104K | Missense Mutation (SNP) | VAF 51/187 reads (27%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as CM1510961, COSV57705814; called by muse, mutect2, varscan2
- RIPK4 | c.2180G>A p.R727H (on ENST00000352483; = p.R679H on NM_020639.3) | Missense Mutation (SNP) | VAF 40/134 reads (30%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.603); catalogued as rs200745554, COSV60187140; called by muse, mutect2, varscan2
- RMI1 | c.398G>A p.R133Q | Missense Mutation (SNP) | VAF 24/269 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs746682840, COSV100366015; called by muse, mutect2
- SLC38A10 | c.820C>T p.R274C | Missense Mutation (SNP) | VAF 72/156 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201350859; called by muse, mutect2, varscan2
- SPG7 | c.2165C>T p.A722V (on ENST00000268704; = p.A729V on NM_003119.4) | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV51948912; called by muse, mutect2, varscan2
- ST8SIA1 | c.736C>A p.Q246K | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.166); catalogued as COSV53954491, COSV53956212, COSV99682907; called by muse, mutect2, varscan2
- UACA | c.3946G>A p.A1316T | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.587); catalogued as rs1182451243; called by muse, mutect2, varscan2
- UBR5 | c.8187+5G>A | Splice Region (SNP) | VAF 6/38 reads (16%) | catalogued as COSV55282280; called by muse, mutect2, varscan2
- VWA2 | c.354C>G p.I118M | Missense Mutation (SNP) | VAF 15/220 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.224); catalogued as COSV100073250; called by muse, mutect2
- WASHC5 | c.2801T>C p.I934T | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs1434612163; called by muse, mutect2, varscan2
- ZIC1 | c.313C>T p.R105W | Missense Mutation (SNP) | VAF 42/84 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51554228; called by muse, mutect2, varscan2
- ABCC1 | c.1809C>G p.I603M | Missense Mutation (SNP) | VAF 41/87 reads (47%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ABCC9 | c.1694A>T p.N565I | Missense Mutation (SNP) | VAF 17/142 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ACSM2B | c.559A>T p.S187C | Missense Mutation (SNP) | VAF 72/219 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- ADARB2 | c.860G>A p.R287H | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- ADRB1 | c.524C>T p.A175V | Missense Mutation (SNP) | VAF 79/200 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- AHCTF1 | c.700C>T p.H234Y (on ENST00000366508; = p.H208Y on NM_015446.5) | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- CCDC172 | c.98G>T p.R33I | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.576); called by muse, mutect2, varscan2
- CCNE1 | c.111+2dup p.X37_splice | Splice Site (INS) | VAF 8/74 reads (11%) | called by mutect2, varscan2
- CLEC17A | c.1061A>G p.N354S | Missense Mutation (SNP) | VAF 113/220 reads (51%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.581); called by muse, mutect2, varscan2
- CLSPN | c.3469G>A p.D1157N | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- CNOT4 | c.154C>G p.L52V | Missense Mutation (SNP) | VAF 47/133 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- CRAMP1 | c.760C>G p.R254G | Missense Mutation (SNP) | VAF 29/47 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CRISP3 | c.352C>A p.P118T (on ENST00000371159 / NM_001368123.1; = p.P100T on NM_006061.4) | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- DENND3 | c.1870_1873del p.I624Wfs*14 | Frame Shift Del (DEL) | VAF 26/88 reads (30%) | called by mutect2, pindel, varscan2
- DEPDC5 | c.1287+1G>A p.X429_splice | Splice Site (SNP) | VAF 5/52 reads (10%) | called by muse, mutect2, varscan2
- DMXL1 | c.565-1G>T p.X189_splice | Splice Site (SNP) | VAF 32/72 reads (44%) | called by muse, mutect2
- DNAH8 | c.7247A>C p.Y2416S | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- ECPAS | c.1256A>T p.K419I | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2
- EFCAB6 | c.3752C>T p.A1251V | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.433); called by muse, mutect2, varscan2
- ELAPOR2 | c.574T>C p.Y192H (on ENST00000450689 / NM_001142749.3; = p.Y25H on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/137 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- FAM171A1 | c.1132T>C p.S378P | Missense Mutation (SNP) | VAF 39/112 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.486); called by muse, mutect2, varscan2
- FBXO32 | c.424C>T p.Q142* | Nonsense Mutation (SNP) | VAF 41/85 reads (48%) | called by muse, mutect2, varscan2
- FOSL2 | c.49A>G p.S17G | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.522); called by muse, mutect2
- FSIP2 | c.7912A>G p.N2638D | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- GALR1 | c.82G>A p.G28S | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- GUCA1B | c.379G>T p.A127S | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- HMGB1 | c.126dup p.K43* | Frame Shift Ins (INS) | VAF 8/18 reads (44%) | called by mutect2, pindel
- IFNL1 | c.345C>A p.D115E | Missense Mutation (SNP) | VAF 56/128 reads (44%) | SIFT tolerated (0.33); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- IGHV2-70D | c.326T>C p.V109A | Missense Mutation (SNP) | VAF 31/34 reads (91%) | SIFT tolerated (0.63); PolyPhen benign (0.013); called by muse, varscan2
- IGHV2-70D | c.302T>C p.L101P | Missense Mutation (SNP) | VAF 38/41 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, varscan2
- IGHV2-70D | c.238T>A p.Y80N | Missense Mutation (SNP) | VAF 46/48 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- IGKV2D-28 | c.266G>A p.G89D | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); called by mutect2, varscan2
- KBTBD6 | c.689G>C p.S230T | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- KCNV2 | c.1608C>A p.N536K | Missense Mutation (SNP) | VAF 94/236 reads (40%) | SIFT tolerated (0.64); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- KMT2A | c.7604C>T p.S2535F | Missense Mutation (SNP) | VAF 102/269 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.483); called by muse, mutect2, varscan2
- KRT24 | c.1051G>A p.A351T | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated (0.54); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- LUZP1 | c.3057C>A p.N1019K | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- MALRD1 | c.5857C>T p.P1953S | Missense Mutation (SNP) | VAF 50/104 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.005); called by muse, mutect2
- MBOAT2 | c.1180A>G p.R394G | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- MLXIPL | c.1424T>A p.L475Q | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.23); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- MUC5B | c.15856C>G p.P5286A | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.679); called by muse, mutect2, varscan2
- NFE2L3 | c.1090T>C p.F364L | Missense Mutation (SNP) | VAF 33/311 reads (11%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCNX2 | c.4205G>A p.C1402Y | Missense Mutation (SNP) | VAF 108/404 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- PGP | c.92del p.L31Rfs*149 | Frame Shift Del (DEL) | VAF 4/9 reads (44%) | called by mutect2, varscan2
- PRRC2C | c.7264C>A p.L2422I (on ENST00000367742; = p.L2420I on NM_015172.4) | Missense Mutation (SNP) | VAF 134/477 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- RBM27 | c.2302C>T p.Q768* | Nonsense Mutation (SNP) | VAF 37/119 reads (31%) | called by muse, mutect2, varscan2
- RGS9 | c.57+1G>A p.X19_splice | Splice Site (SNP) | VAF 7/19 reads (37%) | called by muse, mutect2
- RTL9 | c.3558G>A p.M1186I | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SAMHD1 | c.1468G>C p.D490H | Missense Mutation (SNP) | VAF 21/281 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.108); called by muse, mutect2
- SCN2A | c.3038G>T p.G1013V | Missense Mutation (SNP) | VAF 41/87 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- SCYL2 | c.2405G>A p.G802E | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- SPOPL | c.726A>C p.E242D | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2
- TCOF1 | c.2734G>T p.A912S (on ENST00000377797 / NM_001135243.1; = p.A835S on NM_000356.4) | Missense Mutation (SNP) | VAF 64/118 reads (54%) | SIFT tolerated (0.36); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- USH2A | c.10213G>T p.A3405S | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- UTRN | c.1064T>C p.F355S | Missense Mutation (SNP) | VAF 46/140 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- YLPM1 | c.4625C>T p.P1542L | Missense Mutation (SNP) | VAF 45/131 reads (34%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.338); called by muse, mutect2, varscan2
- ZBTB37 | c.241G>C p.E81Q | Missense Mutation (SNP) | VAF 76/362 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, varscan2
- ZBTB37 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 43/287 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.099); called by muse, varscan2
- ABCB5 | c.2616T>C p.H872= (on ENST00000404938 / NM_001163941.2; = p.H427= on NM_178559.6) | Silent (SNP) | VAF 65/147 reads (44%) | catalogued as COSV51714120, COSV51724815; called by muse, mutect2, varscan2
- ABCG1 | c.96G>A p.S32= | Silent (SNP) | VAF 28/102 reads (27%) | catalogued as rs554693689; called by muse, mutect2, varscan2
- ACKR4 | c.696C>T p.N232= | Silent (SNP) | VAF 87/236 reads (37%) | catalogued as rs767597534; called by muse, mutect2, varscan2
- ACTRT2 | c.586C>T p.L196= | Silent (SNP) | VAF 59/118 reads (50%) | called by muse, mutect2, varscan2
- ARHGAP24 | c.1353C>T p.T451= (on ENST00000395184 / NM_001025616.3; = p.T358= on NM_031305.3) | Silent (SNP) | VAF 17/73 reads (23%) | called by muse, mutect2, varscan2
- ATP2C1 | c.2622C>T p.S874= | Silent (SNP) | VAF 88/181 reads (49%) | catalogued as rs1177625730; called by muse, mutect2, varscan2
- C8orf48 | c.924C>T p.I308= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as COSV52047779; called by muse, mutect2, varscan2
- CCL13 | c.273G>C p.R91= | Silent (SNP) | VAF 163/336 reads (49%) | called by muse, varscan2
- CD248 | c.726C>T p.C242= | Silent (SNP) | VAF 44/95 reads (46%) | catalogued as rs190495509; called by muse, mutect2, varscan2
- CDK13 | c.4206T>C p.S1402= | Silent (SNP) | VAF 34/87 reads (39%) | catalogued as COSV51706733; called by muse, mutect2, varscan2
- DBNL | c.315C>T p.A105= | Silent (SNP) | VAF 9/82 reads (11%) | called by muse, mutect2, varscan2
- DNAH14 | c.2982A>C p.S994= (on ENST00000445597; = p.S1168= on NM_001367479.1) | Silent (SNP) | VAF 61/251 reads (24%) | called by muse, mutect2, varscan2
- EPG5 | c.2751T>A p.A917= | Silent (SNP) | VAF 18/150 reads (12%) | called by muse, mutect2, varscan2
- GRWD1 | c.1323C>T p.F441= | Silent (SNP) | VAF 77/156 reads (49%) | called by muse, mutect2, varscan2
- IGHG1 | c.645C>T p.I215= | Silent (SNP) | VAF 13/21 reads (62%) | catalogued as rs371914572; called by muse, mutect2, varscan2
- IL20RA | c.480G>A p.K160= | Silent (SNP) | VAF 68/146 reads (47%) | called by muse, mutect2, varscan2
- LARGE1 | c.1425C>A p.T475= | Silent (SNP) | VAF 4/58 reads (7%) | called by muse, mutect2
- LRRC30 | c.192C>G p.P64= | Silent (SNP) | VAF 52/129 reads (40%) | catalogued as COSV101274385, COSV67301906; called by muse, mutect2, varscan2
- MCRIP2 | c.471C>T p.T157= | Silent (SNP) | VAF 33/85 reads (39%) | catalogued as rs763681789, COSV99553278; called by muse, mutect2, varscan2
- MRGPRE | c.585C>T p.A195= | Silent (SNP) | VAF 12/36 reads (33%) | called by muse, mutect2, varscan2
- OR56A5 | c.51C>T p.L17= | Silent (SNP) | VAF 20/55 reads (36%) | called by muse, mutect2, varscan2
- PLAT | c.882C>T p.P294= | Silent (SNP) | VAF 30/75 reads (40%) | called by muse, mutect2, varscan2
- PRICKLE2 | c.522C>T p.V174= (on ENST00000295902; = p.V118= on NM_198859.4) | Silent (SNP) | VAF 43/96 reads (45%) | catalogued as rs539996562; called by muse, mutect2, varscan2
- SEPTIN5 | c.786C>G p.G262= | Silent (SNP) | VAF 23/66 reads (35%) | called by muse, mutect2, varscan2
- SLC45A2 | c.1566C>A p.V522= | Silent (SNP) | VAF 88/184 reads (48%) | catalogued as rs762123246, COSV56873758; called by muse, mutect2, varscan2
- WDR35 | c.1497C>T p.T499= (on ENST00000345530 / NM_001006657.2; = p.T488= on NM_020779.4) | Silent (SNP) | VAF 31/69 reads (45%) | catalogued as rs566888481; called by muse, mutect2, varscan2
- ZNF490 | c.255G>A p.V85= | Silent (SNP) | VAF 13/184 reads (7%) | catalogued as rs376155605; called by muse, mutect2
- AC136628.2 | n.754G>A | RNA (SNP) | VAF 122/251 reads (49%) | catalogued as rs1047258045; called by muse, mutect2, varscan2
- AC244258.1 | n.816T>C | RNA (SNP) | VAF 41/113 reads (36%) | called by muse, mutect2, varscan2
- ACACB | c.5670-629T>C | Intron (SNP) | VAF 15/43 reads (35%) | called by muse, mutect2, varscan2
- ACAT2 | chr6:159762044 T>A | 5'Flank (SNP) | VAF 29/55 reads (53%) | called by muse, mutect2, varscan2
- ACSL4 | c.-369T>C | 5'UTR (SNP) | VAF 8/8 reads (100%) | catalogued as rs769082144; called by muse, varscan2
- ADAM22 | chr7:88201079 G>A | 3'Flank (SNP) | VAF 16/37 reads (43%) | called by muse, mutect2, varscan2
- AGTR2 | c.*62T>G | 3'UTR (SNP) | VAF 83/84 reads (99%) | called by muse, mutect2, varscan2
- AMPH | c.1183-1089A>C | Intron (SNP) | VAF 58/137 reads (42%) | called by muse, mutect2, varscan2
- ANGEL1 | c.*197C>G | 3'UTR (SNP) | VAF 30/52 reads (58%) | catalogued as rs904659900; called by muse, mutect2, varscan2
- ANGEL2 | c.*2128A>C | 3'UTR (SNP) | VAF 25/109 reads (23%) | called by muse, mutect2, varscan2
- ARID4A | c.*602C>T | 3'UTR (SNP) | VAF 41/82 reads (50%) | called by muse, mutect2, varscan2
- BCAP29 | c.-15+214G>A | Intron (SNP) | VAF 10/46 reads (22%) | called by muse, mutect2, varscan2
- BCAT1 | c.*2915A>C | 3'UTR (SNP) | VAF 6/106 reads (6%) | called by muse, mutect2
- BMPR2 | c.*3514A>G | 3'UTR (SNP) | VAF 17/35 reads (49%) | called by muse, mutect2, varscan2
- BPNT1 | c.*422C>T | 3'UTR (SNP) | VAF 25/141 reads (18%) | called by muse, mutect2, varscan2
- CALD1 | c.-11G>A | 5'UTR (SNP) | VAF 112/243 reads (46%) | called by muse, mutect2, varscan2
- CAMK2D | chr4:113761468 A>C | 5'Flank (SNP) | VAF 15/18 reads (83%) | called by muse, mutect2, varscan2
- CAMK4 | c.*1942T>C | 3'UTR (SNP) | VAF 36/69 reads (52%) | called by muse, mutect2, varscan2
- CASQ2 | c.-81G>T | 5'UTR (SNP) | VAF 5/48 reads (10%) | called by muse, mutect2
- CCNL2 | c.*209C>T | 3'UTR (SNP) | VAF 12/126 reads (10%) | catalogued as rs377266295; called by muse, mutect2, varscan2
- CD33 | c.843-26T>C | Intron (SNP) | VAF 24/52 reads (46%) | catalogued as rs558681033; called by muse, mutect2, varscan2
- CFAP43 | c.1442+43G>A | Intron (SNP) | VAF 34/73 reads (47%) | catalogued as rs377069039; called by muse, mutect2, varscan2
- CMKLR1 | c.*345A>G | 3'UTR (SNP) | VAF 41/125 reads (33%) | called by muse, mutect2, varscan2
- COG5 | c.2312+2530A>G | Intron (SNP) | VAF 9/77 reads (12%) | called by muse, mutect2, varscan2
- COL10A1 | c.*593G>C | 3'UTR (SNP) | VAF 37/73 reads (51%) | called by muse, mutect2, varscan2
- COLGALT2 | c.1137-439G>T | Intron (SNP) | VAF 50/201 reads (25%) | called by muse, mutect2, varscan2
- COMMD9 | c.317+89T>G | Intron (SNP) | VAF 15/42 reads (36%) | called by mutect2, varscan2
- CTC1 | c.435+54A>G | Intron (SNP) | VAF 32/69 reads (46%) | called by muse, mutect2, varscan2
- CYTH4 | c.*1703_*1715del | 3'UTR (DEL) | VAF 20/80 reads (25%) | called by mutect2, varscan2
- DNAJC25 | c.*483G>T | 3'UTR (SNP) | VAF 40/115 reads (35%) | called by muse, mutect2, varscan2
- DTX3L | c.*187G>A | 3'UTR (SNP) | VAF 36/100 reads (36%) | called by muse, mutect2, varscan2
- EGR1 | c.-94C>T | 5'UTR (SNP) | VAF 16/24 reads (67%) | catalogued as rs1443912787, COSV53521276; called by muse, mutect2, varscan2
- EGR1 | c.-93C>T | 5'UTR (SNP) | VAF 16/24 reads (67%) | catalogued as rs1338185649, COSV99525462; called by muse, mutect2, varscan2
- EN1 | c.*44C>T | 3'UTR (SNP) | VAF 12/40 reads (30%) | called by muse, mutect2, varscan2
- FCMR | c.*1203A>G | 3'UTR (SNP) | VAF 20/211 reads (9%) | called by muse, mutect2
- FCRLA | c.-10G>C | 5'UTR (SNP) | VAF 9/247 reads (4%) | catalogued as COSV99375720; called by muse, mutect2
- FPGT-TNNI3K | c.2114+596G>T | Intron (SNP) | VAF 33/69 reads (48%) | called by muse, mutect2, varscan2
- FRMPD4 | c.*1139G>A | 3'UTR (SNP) | VAF 160/169 reads (95%) | called by muse, mutect2, varscan2
- G3BP1 | c.*1492G>A | 3'UTR (SNP) | VAF 8/77 reads (10%) | called by muse, mutect2, varscan2
- GFRA2 | chr8:21690482 del GGAAT | 3'Flank (DEL) | VAF 13/52 reads (25%) | called by mutect2, pindel, varscan2
- GPR107 | c.*1208T>A | 3'UTR (SNP) | VAF 14/67 reads (21%) | called by muse, mutect2, varscan2
- GRHL1 | c.278+12T>C | Intron (SNP) | VAF 25/210 reads (12%) | called by muse, mutect2, varscan2
- GSX2 | c.-25C>T | 5'UTR (SNP) | VAF 67/111 reads (60%) | called by muse, mutect2, varscan2
- HDAC7 | chr12:47783205 T>A | 3'Flank (SNP) | VAF 79/168 reads (47%) | called by muse, mutect2, varscan2
- HEATR3 | c.*1190G>A | 3'UTR (SNP) | VAF 10/41 reads (24%) | catalogued as rs1352352494; called by muse, mutect2, varscan2
- HNRNPK | c.*814T>G | 3'UTR (SNP) | VAF 120/243 reads (49%) | called by muse, mutect2, varscan2
- HOXA3 | chr7:27106726 G>A | 3'Flank (SNP) | VAF 32/79 reads (41%) | called by muse, mutect2, varscan2
- IL1R1 | c.*2636C>A | 3'UTR (SNP) | VAF 13/95 reads (14%) | called by muse, mutect2, varscan2
- KRT6C | c.*191A>G | 3'UTR (SNP) | VAF 5/37 reads (14%) | called by muse, mutect2, varscan2
- KRTAP19-5 | c.*135C>T | 3'UTR (SNP) | VAF 17/143 reads (12%) | called by muse, mutect2, varscan2
- LGALS8 | c.-104+191G>A | Intron (SNP) | VAF 14/99 reads (14%) | called by muse, mutect2, varscan2
- LINC01299 | n.1055G>A | RNA (SNP) | VAF 54/133 reads (41%) | called by muse, mutect2, varscan2
- MAN1C1 | c.*2387G>A | 3'UTR (SNP) | VAF 25/61 reads (41%) | called by muse, mutect2, varscan2
- MAN2B2 | c.2815-1103C>T | Intron (SNP) | VAF 56/107 reads (52%) | catalogued as rs537782360; called by muse, mutect2, varscan2
- MAS1L | c.*64T>G | 3'UTR (SNP) | VAF 26/75 reads (35%) | called by muse, mutect2, varscan2
- MCC | c.*2303C>T | 3'UTR (SNP) | VAF 3/30 reads (10%) | called by muse, mutect2
- METTL4 | c.-323C>T | 5'UTR (SNP) | VAF 21/54 reads (39%) | called by muse, mutect2, varscan2
- MGAT4A | c.-89A>T | 5'UTR (SNP) | VAF 16/225 reads (7%) | called by muse, mutect2
- MPRIP | c.123+14716C>T | Intron (SNP) | VAF 92/332 reads (28%) | catalogued as rs754882461; called by muse, varscan2
- MRPS10 | c.*240C>T | 3'UTR (SNP) | VAF 11/288 reads (4%) | called by muse, mutect2
- MSC | c.534+309G>T | Intron (SNP) | VAF 23/39 reads (59%) | called by muse, mutect2, varscan2
- MSR1 | c.1034-330T>C | Intron (SNP) | VAF 7/32 reads (22%) | catalogued as rs1182539025, COSV50519000; called by muse, mutect2, varscan2
- MTMR8 | c.*2T>G | 3'UTR (SNP) | VAF 4/97 reads (4%) | called by muse, mutect2
- MXD1 | c.*1114C>A | 3'UTR (SNP) | VAF 35/81 reads (43%) | called by muse, mutect2, varscan2
- MYLIP | c.*583A>G | 3'UTR (SNP) | VAF 44/102 reads (43%) | catalogued as rs577343919; called by muse, mutect2, varscan2
- NADK | c.*1154G>C | 3'UTR (SNP) | VAF 14/231 reads (6%) | called by muse, mutect2
- NR2F2 | c.*119A>C | 3'UTR (SNP) | VAF 52/113 reads (46%) | called by muse, mutect2, varscan2
- NUDT9P1 | n.633G>T | RNA (SNP) | VAF 64/147 reads (44%) | called by muse, mutect2, varscan2
- ONECUT2 | c.*6687C>G | 3'UTR (SNP) | VAF 6/90 reads (7%) | called by muse, mutect2
- PAIP2B | c.*3088G>A | 3'UTR (SNP) | VAF 15/174 reads (9%) | called by muse, mutect2
- PAX7 | c.*2924G>C | 3'UTR (SNP) | VAF 8/106 reads (8%) | called by muse, mutect2
- PGBD5 | chr1:230322648 G>A | 3'Flank (SNP) | VAF 31/106 reads (29%) | catalogued as rs1219451500; called by muse, mutect2, varscan2
- PLEKHG4B | c.*4825C>G | 3'UTR (SNP) | VAF 25/49 reads (51%) | called by muse, mutect2, varscan2
- PMEPA1 | c.*2208C>T | 3'UTR (SNP) | VAF 37/101 reads (37%) | called by muse, mutect2, varscan2
- PNN | c.*1305T>A | 3'UTR (SNP) | VAF 29/81 reads (36%) | called by muse, mutect2, varscan2
- PNPT1 | c.*675+217C>G | Intron (SNP) | VAF 7/16 reads (44%) | called by muse, mutect2, varscan2
- POLE2 | chr14:49688309 C>A | 5'Flank (SNP) | VAF 49/112 reads (44%) | catalogued as rs1166078644; called by muse, mutect2, varscan2
- PRRC1 | c.1128+1677A>C | Intron (SNP) | VAF 25/49 reads (51%) | called by muse, mutect2, varscan2
- PRRG1 | c.*873C>T | 3'UTR (SNP) | VAF 44/46 reads (96%) | called by muse, mutect2, varscan2
- PTPN5 | c.1330-728G>A | Intron (SNP) | VAF 30/58 reads (52%) | catalogued as rs573717992; called by muse, mutect2, varscan2
- PTPRN2 | c.2344+5851C>T | Intron (SNP) | VAF 42/84 reads (50%) | catalogued as rs199501985; called by muse, mutect2, varscan2
- RAPGEF5 | c.*1116T>C | 3'UTR (SNP) | VAF 20/40 reads (50%) | called by muse, mutect2, varscan2
- RPL27A | c.4-140G>A | Intron (SNP) | VAF 50/102 reads (49%) | called by muse, mutect2, varscan2
- SEMA3A | c.*2696dup | 3'UTR (INS) | VAF 30/68 reads (44%) | catalogued as rs1468979622; called by mutect2, varscan2
- SF3A1 | c.*443A>T | 3'UTR (SNP) | VAF 23/44 reads (52%) | called by muse, mutect2, varscan2
- SGK1 | c.77-43A>C | Intron (SNP) | VAF 186/382 reads (49%) | called by muse, mutect2, varscan2
- SIM1 | chr6:100387331 C>A | 3'Flank (SNP) | VAF 41/111 reads (37%) | catalogued as rs1466388228; called by muse, mutect2, varscan2
- SKIDA1 | c.-179C>G | 5'UTR (SNP) | VAF 50/98 reads (51%) | catalogued as rs979413962; called by mutect2, varscan2
- SLC13A3 | c.*1349C>G | 3'UTR (SNP) | VAF 30/87 reads (34%) | called by muse, mutect2, varscan2
- SNX21 | c.22-114G>T | Intron (SNP) | VAF 6/27 reads (22%) | called by muse, mutect2, varscan2
- SPTA1 | c.*93G>A | 3'UTR (SNP) | VAF 121/465 reads (26%) | catalogued as rs929301791, COSV100778911; called by muse, mutect2, varscan2
- TCF21 | c.*2341A>T | 3'UTR (SNP) | VAF 6/39 reads (15%) | called by muse, mutect2, varscan2
- TEAD1 | c.*4043A>T | 3'UTR (SNP) | VAF 27/97 reads (28%) | called by muse, mutect2, varscan2
- THBS2 | c.*1385T>C | 3'UTR (SNP) | VAF 31/64 reads (48%) | catalogued as rs1410664509; called by muse, mutect2, varscan2
- TSPAN1 | c.*371C>A | 3'UTR (SNP) | VAF 4/40 reads (10%) | called by muse, mutect2
- TTC29 | c.977+2106G>A | Intron (SNP) | VAF 4/22 reads (18%) | catalogued as rs769207059; called by muse, mutect2, varscan2
- TTPAL | c.*3887G>A | 3'UTR (SNP) | VAF 9/61 reads (15%) | called by muse, mutect2, varscan2
- UGT2A3 | c.*112A>T | 3'UTR (SNP) | VAF 36/207 reads (17%) | catalogued as rs891196939; called by muse, mutect2, varscan2
- YY1 | c.*1551C>T | 3'UTR (SNP) | VAF 23/78 reads (29%) | called by muse, mutect2, varscan2
- ZFP37 | c.*1459T>A | 3'UTR (SNP) | VAF 41/77 reads (53%) | called by muse, mutect2, varscan2
- ZMPSTE24 | c.*804C>G | 3'UTR (SNP) | VAF 33/81 reads (41%) | called by muse, mutect2, varscan2
- ZNF780A | chr19:40071487 T>G | 3'Flank (SNP) | VAF 32/64 reads (50%) | called by muse, mutect2, varscan2
- ZNF831 | c.*2305A>C | 3'UTR (SNP) | VAF 42/82 reads (51%) | called by muse, mutect2, varscan2
- ZNF844 | c.*2022C>A | 3'UTR (SNP) | VAF 14/23 reads (61%) | called by muse, mutect2, varscan2
